Gene-level copy-number profile of tumor specimen TCGA-UZ-A9PQ-01A from TCGA case TCGA-UZ-A9PQ, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III.
Specimen TCGA-UZ-A9PQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KIRP.bc56c6e2-5bb9-4d73-8182-bc707823d043.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-UZ-A9PQ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS.
https://portal.gdc.cancer.gov/files/fbca3957-9366-467e-87d1-283981d31039

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 15,104; copy number 2: 41,496; copy number 3: 2,583; copy number 4: 76; copy number 5: 93; copy number 6: 45; copy number 8: 47; copy number 9: 167; copy number 11: 34; copy number 13: 18; copy number 14: 52; copy number 15: 61; copy number 16: 21.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:160,698,288–161,117,385, 11 genes: AL109933.1, PLG, AL109933.5, AL109933.4, AL109933.3, AL391361.2, AL391361.1, AL139393.2, AL139393.1, MAP3K4-AS1, MAP3K4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 538 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:41,026,895–54,945,099, 313 genes, copy number 5–16 (broad region; genes not listed).
- chr6:55,434,373–55,940,624, 4 genes, copy number 5 (within-gene range 5–7): HMGCLL1, AL590290.1, BMP5, NPM1P36.
- chr10:5,498,697–8,075,198, 61 genes, copy number 6–11 (broad region; genes not listed).
- chr10:8,400,860–8,973,468, 8 genes, copy number 5: AC025946.1, AC025946.2, KRT8P37, CHCHD3P1, RNA5SP299, AL355333.1, LINC02676, AC044784.1.
- chr10:9,721,963–14,462,142, 77 genes, copy number 9–11 (within-gene range 2–11) (broad region; genes not listed).
- chr10:14,518,557–15,139,818, 20 genes, copy number 8 (within-gene range 2–8): FAM107B, AL158168.1, RNA5SP302, RPSAP7, CDNF, AC069544.2, HSPA14, AC069544.1, SUV39H2, DCLRE1C, MEIG1, OR7E110P, OR7E26P, OR7E115P, DCLRE1CP1, OLAH, ACBD7, GAPDHP45, RPP38-DT, RPP38.
- chr10:19,048,801–19,790,401, 1 gene, copy number 5 (within-gene range 4–5): MALRD1.
- chr10:19,290,223–21,743,630, 38 genes, copy number 5: AL590378.1, HMGN1P20, AL354695.1, U3, RNA5SP303, AL157895.1, MTND1P37, MTND2P16, RNU6-1212P, AL353147.1, PLXDC2, AC069549.1, AC069549.2, AMD1P1, AL590032.1, MIR4675, NEBL, MTND1P21, AL157398.1, EIF4BP2, NPM1P30, NEBL-AS1, AL731547.1, LUZP4P1, RNU6-15P, LINC02643, RNMTL1P1, AL158209.1, Metazoa_SRP, Y_RNA, MIR1915HG, MIR1915, SKIDA1, MLLT10, AL358780.1, RNU6-306P, HNRNPRP1, RNU6-1141P.
- chr10:22,345,445–22,787,499, 7 genes, copy number 8 (within-gene range 1–8): SPAG6, AL513128.1, AL513128.3, AL513128.2, PIP4K2A, AL390318.1, RNU6-413P.
- chr10:25,174,802–25,933,710, 9 genes, copy number 8 (within-gene range 1–8): GPR158, AL354976.1, RN7SKP220, GPN3P1, LINC00836, HIRAP1, RNA5SP306, RNU6-632P, AL358612.1.

Autosomal genes at a single copy (total copy number 1): 12,717. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
